Somatic mutation profile of cancer-model specimen HCM-CSHL-0366-C50-85B (3D Organoid; aliquot HCM-CSHL-0366-C50-85B-01D-A78J-36), derived from the primary tumor of HCMI case HCM-CSHL-0366-C50, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Metaplastic carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 46.9 years (17,140 days).
Specimen HCM-CSHL-0366-C50-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e4736f90-c154-413a-8537-a3e1fcce4c55.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0366-C50-10A (Blood Derived Normal), aliquot HCM-CSHL-0366-C50-10A-01D-A78J-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/28555d95-a598-430d-9c30-12844ca59056

The open-access MAF lists 144 somatic variants for this specimen: 103 protein-altering or splice-affecting, 24 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 94, Silent 24, Intron 11, Nonsense Mutation 5, 5'UTR 3, Splice Site 2, RNA 1, Frame Shift Ins 1, 5'Flank 1, 3'UTR 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.723dup p.E242* | Frame Shift Ins (INS) | VAF 210/306 reads (69%) | catalogued as rs1060500115; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- TP53 | c.733G>A p.G245S | Missense Mutation (SNP) | VAF 217/246 reads (88%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs28934575, CM010463, CM900210, CM920674, COSV52661744, COSV52661877, COSV52713951, COSV52839866; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ATMIN | c.664G>T p.D222Y | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.4); PolyPhen benign (0.051); catalogued as COSV100214572; called by muse, varscan2
- BHLHE22 | c.544G>A p.E182K | Missense Mutation (SNP) | VAF 77/142 reads (54%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.011); catalogued as rs1296848862, COSV58861327, COSV58863066; called by muse, mutect2, varscan2
- BRCC3 | c.810G>C p.K270N | Missense Mutation (SNP) | VAF 109/246 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV57461779; called by muse, mutect2, varscan2
- CCSER2 | c.995G>T p.G332V | Missense Mutation (SNP) | VAF 120/195 reads (62%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.656); catalogued as COSV56503909; called by muse, mutect2, varscan2
- CHL1 | c.1408C>T p.R470W (on ENST00000397491 / NM_001253387.1; = p.R486W on NM_006614.4) | Missense Mutation (SNP) | VAF 42/262 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs141644867; called by muse, mutect2, varscan2
- COL6A3 | c.2491C>G p.Q831E | Missense Mutation (SNP) | VAF 123/136 reads (90%) | SIFT tolerated (0.48); PolyPhen benign (0.104); catalogued as COSV55115801; called by muse, mutect2, varscan2
- DENND4A | c.2593C>T p.R865C | Missense Mutation (SNP) | VAF 48/119 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as rs756556371; called by muse, mutect2, varscan2
- DIP2A | c.946G>A p.E316K | Missense Mutation (SNP) | VAF 90/252 reads (36%) | SIFT tolerated (0.29); PolyPhen benign (0.043); catalogued as rs1456031785; called by muse, mutect2, varscan2
- DNAAF3 | c.1354G>A p.A452T (on ENST00000524407 / NM_001256715.2; = p.A499T on NM_178837.4) | Missense Mutation (SNP) | VAF 136/530 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs546293010, COSV61277795; called by muse, mutect2, varscan2
- DNAJC5G | c.225C>G p.F75L | Missense Mutation (SNP) | VAF 141/678 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV56081351, COSV56081643; called by muse, mutect2, varscan2
- EME1 | c.405G>C p.W135C | Missense Mutation (SNP) | VAF 104/120 reads (87%) | SIFT tolerated (0.07); PolyPhen benign (0.125); catalogued as COSV99869077; called by mutect2, varscan2
- EMILIN1 | c.2104G>A p.E702K | Missense Mutation (SNP) | VAF 69/169 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs370534632, COSV53154338; called by muse, mutect2, varscan2
- FGF3 | c.670C>A p.H224N | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); catalogued as COSV61925337; called by muse, mutect2, varscan2
- FUT4 | c.604G>C p.D202H | Missense Mutation (SNP) | VAF 102/353 reads (29%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as rs984644159, COSV62469209, COSV62469259, COSV62470017; called by muse, mutect2, varscan2
- GARS1 | c.271G>A p.V91I | Missense Mutation (SNP) | VAF 207/619 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as rs374616031; ClinVar: likely benign; called by muse, mutect2, varscan2
- GRM3 | c.691G>A p.E231K | Missense Mutation (SNP) | VAF 129/197 reads (65%) | SIFT tolerated (0.87); PolyPhen benign (0.223); catalogued as COSV64471712, COSV64478005; called by muse, mutect2, varscan2
- HMCN1 | c.7465G>A p.V2489M | Missense Mutation (SNP) | VAF 118/851 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.747); catalogued as rs1373625415; called by muse, mutect2, varscan2
- KDM6A | c.2995G>C p.E999Q | Missense Mutation (SNP) | VAF 112/138 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV65038034, COSV65040758; called by muse, mutect2, varscan2
- KIF13B | c.2083C>G p.L695V | Missense Mutation (SNP) | VAF 153/380 reads (40%) | SIFT tolerated (0.22); PolyPhen benign (0.171); catalogued as rs1277630291; called by muse, mutect2, varscan2
- KIFC1 | c.1401G>C p.E467D | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV65737888; called by muse, mutect2, varscan2
- LYST | c.8003G>A p.R2668K | Missense Mutation (SNP) | VAF 144/293 reads (49%) | SIFT tolerated (0.99); PolyPhen benign (0); catalogued as rs1416779664; called by muse, mutect2, varscan2
- MUC4 | c.7201C>T p.L2401F | Missense Mutation (SNP) | VAF 413/2361 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.598); catalogued as rs752525044; called by muse, mutect2, varscan2
- MUC6 | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 36/325 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs547156930, COSV70133356; called by muse, mutect2, varscan2
- MVD | c.725G>A p.R242H | Missense Mutation (SNP) | VAF 101/247 reads (41%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as rs1177828138, COSV55367769; called by muse, mutect2, varscan2
- NAPA | c.883C>T p.R295C | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.927); catalogued as rs747809065; called by muse, mutect2, varscan2
- NEFH | c.1585G>C p.E529Q | Missense Mutation (SNP) | VAF 110/205 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.118); catalogued as rs1217375234; called by muse, mutect2, varscan2
- NEFH | c.2857G>C p.E953Q | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.572); catalogued as COSV60216259; called by muse, mutect2, varscan2
- NPIPB15 | c.931C>T p.L311F | Missense Mutation (SNP) | VAF 298/1720 reads (17%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.982); catalogued as rs754177956; called by muse, mutect2
- OR5AP2 | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 137/184 reads (74%) | SIFT tolerated (0.46); PolyPhen benign (0.007); catalogued as COSV100266315; called by muse, mutect2, varscan2
- PCDHGB1 | c.1016A>G p.N339S | Missense Mutation (SNP) | VAF 78/301 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.468); catalogued as rs202007643; called by muse, mutect2, varscan2
- PIEZO2 | c.6383A>T p.Q2128L | Missense Mutation (SNP) | VAF 67/257 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs1228178324, COSV53287407; called by muse, mutect2, varscan2
- PILRA | c.401C>G p.S134* | Nonsense Mutation (SNP) | VAF 220/480 reads (46%) | catalogued as rs1475095141; called by muse, mutect2, varscan2
- PLVAP | c.202G>A p.E68K | Missense Mutation (SNP) | VAF 119/248 reads (48%) | SIFT tolerated (0.11); PolyPhen benign (0.353); catalogued as rs148432183, COSV53086417; called by muse, mutect2, varscan2
- POLQ | c.7321C>T p.Q2441* | Nonsense Mutation (SNP) | VAF 175/301 reads (58%) | catalogued as rs777186145, COSV99953238; called by muse, mutect2, varscan2
- POM121L2 | c.444G>C p.E148D | Missense Mutation (SNP) | VAF 88/403 reads (22%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.979); catalogued as COSV66277434; called by muse, mutect2, varscan2
- RAD51C | c.853C>T p.Q285* | Nonsense Mutation (SNP) | VAF 77/204 reads (38%) | catalogued as COSV61677447; called by muse, mutect2, varscan2
- RAPGEF6 | c.928G>A p.E310K | Missense Mutation (SNP) | VAF 47/141 reads (33%) | SIFT tolerated (0.53); PolyPhen benign (0.013); catalogued as rs1162961940, COSV99726095; called by muse, mutect2, varscan2
- RBBP4 | c.169G>A p.E57K | Missense Mutation (SNP) | VAF 38/73 reads (52%) | SIFT tolerated (0.58); PolyPhen benign (0.01); catalogued as COSV65132517; called by mutect2, varscan2
- RBM23 | c.412G>A p.G138R (on ENST00000359890 / NM_001077351.2; = p.G122R on NM_018107.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/170 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.009); catalogued as COSV100321327; called by muse, mutect2, varscan2
- RPS6KA2 | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.023); catalogued as rs1446087210, COSV101551551; called by muse, mutect2, varscan2
- SERPINE3 | c.358G>A p.G120R | Missense Mutation (SNP) | VAF 274/544 reads (50%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.457); catalogued as COSV68546061; called by muse, mutect2, varscan2
- SLC12A2 | c.1330C>T p.L444F | Missense Mutation (SNP) | VAF 47/264 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.632); catalogued as COSV52475281; called by muse, mutect2, varscan2
- SOX6 | c.1440C>G p.I480M (on ENST00000528429 / NM_001145819.2; = p.I453M on NM_017508.3) | Missense Mutation (SNP) | VAF 56/157 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.737); catalogued as rs1464496710, COSV99074036; called by muse, mutect2, varscan2
- SYNE1 | c.2360C>T p.A787V (on ENST00000367255 / NM_182961.4; = p.A794V on NM_033071.3) | Missense Mutation (SNP) | VAF 143/313 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.23); catalogued as rs147406318, COSV54951838; called by muse, mutect2, varscan2
- TBX2 | c.1437C>G p.F479L | Missense Mutation (SNP) | VAF 63/138 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as COSV104383109; called by muse, mutect2, varscan2
- TEX49 | c.80-1G>A p.X27_splice | Splice Site (SNP) | VAF 50/120 reads (42%) | catalogued as rs767354203; called by mutect2, varscan2
- TSSC4 | c.460G>A p.D154N | Missense Mutation (SNP) | VAF 20/154 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763464142, COSV50174081; called by muse, mutect2, varscan2
- ZFYVE26 | c.6005G>A p.C2002Y | Missense Mutation (SNP) | VAF 166/1105 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61328817; called by muse, mutect2, varscan2
- ZNF423 | c.2302C>A p.R768S (on ENST00000563137 / NM_001379286.1; = p.R760S on NM_015069.4) | Missense Mutation (SNP) | VAF 85/303 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV52183452; called by muse, mutect2, varscan2
- ZNF469 | c.1164G>T p.Q388H | Missense Mutation (SNP) | VAF 218/575 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1430171586; called by muse, mutect2, varscan2
- AAAS | c.829G>A p.E277K | Missense Mutation (SNP) | VAF 70/238 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- ADAM2 | c.1439A>G p.N480S | Missense Mutation (SNP) | VAF 44/134 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.42); called by muse, mutect2, varscan2
- ADGRG6 | c.1417G>A p.E473K | Missense Mutation (SNP) | VAF 48/177 reads (27%) | SIFT tolerated (0.61); PolyPhen benign (0); called by muse, mutect2, varscan2
- CACHD1 | c.226G>T p.E76* | Nonsense Mutation (SNP) | VAF 57/283 reads (20%) | called by muse, mutect2, varscan2
- CAT | c.290C>T p.A97V | Missense Mutation (SNP) | VAF 124/332 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- CCDC3 | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.669); called by muse, mutect2, varscan2
- CNGA1 | c.319G>C p.E107Q | Missense Mutation (SNP) | VAF 48/90 reads (53%) | SIFT tolerated (0.17); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- CNGB1 | c.3254G>C p.R1085T | Missense Mutation (SNP) | VAF 206/531 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- COL15A1 | c.1609C>T p.P537S | Missense Mutation (SNP) | VAF 48/119 reads (40%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- CT83 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 64/122 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- CUL9 | c.7486G>C p.E2496Q | Missense Mutation (SNP) | VAF 83/319 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- CYP3A4 | c.781C>T p.L261F | Missense Mutation (SNP) | VAF 36/187 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- DAGLB | c.935G>A p.R312K | Missense Mutation (SNP) | VAF 82/243 reads (34%) | SIFT tolerated (0.42); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DGKG | c.1034C>T p.S345F | Missense Mutation (SNP) | VAF 90/370 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- DPYS | c.213G>T p.Q71H | Missense Mutation (SNP) | VAF 135/399 reads (34%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- EPB41L4B | c.969G>C p.L323F | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- EXOSC8 | c.557A>G p.Y186C | Missense Mutation (SNP) | VAF 32/87 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAM189A1 | c.1199A>G p.D400G | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.516); called by muse, mutect2
- FBXO4 | c.653G>C p.G218A | Missense Mutation (SNP) | VAF 39/173 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- FERMT1 | c.307A>T p.N103Y | Missense Mutation (SNP) | VAF 231/504 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- FLNA | c.7769T>A p.L2590Q (on ENST00000369850 / NM_001110556.2; = p.L2582Q on NM_001456.3) | Missense Mutation (SNP) | VAF 57/271 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- HHIPL1 | c.1814-1G>A p.X605_splice | Splice Site (SNP) | VAF 7/13 reads (54%) | called by muse, mutect2
- IMPG1 | c.724C>G p.L242V | Missense Mutation (SNP) | VAF 78/282 reads (28%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- INAVA | c.952C>T p.P318S | Missense Mutation (SNP) | VAF 48/432 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- JRK | c.977C>T p.S326L | Missense Mutation (SNP) | VAF 91/275 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.597); called by muse, mutect2, varscan2
- KIF27 | c.3284C>T p.A1095V | Missense Mutation (SNP) | VAF 110/269 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.323); called by muse, mutect2, varscan2
- LOXHD1 | c.4789T>A p.W1597R | Missense Mutation (SNP) | VAF 22/267 reads (8%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.583); called by muse, mutect2
- MAPK9 | c.1183G>A p.D395N | Missense Mutation (SNP) | VAF 52/177 reads (29%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- MID1 | c.1105G>A p.E369K | Missense Mutation (SNP) | VAF 80/320 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); called by muse, mutect2, varscan2
- NAA16 | c.2176C>G p.P726A | Missense Mutation (SNP) | VAF 40/50 reads (80%) | SIFT tolerated (0.15); PolyPhen benign (0.009); called by muse, varscan2
- NAA16 | c.2260C>G p.L754V | Missense Mutation (SNP) | VAF 28/36 reads (78%) | SIFT tolerated (0.07); PolyPhen benign (0.362); called by muse, varscan2
- NCAPD3 | c.660A>T p.L220F | Missense Mutation (SNP) | VAF 81/309 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- NPM3 | c.199A>G p.T67A | Missense Mutation (SNP) | VAF 88/193 reads (46%) | SIFT tolerated (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OLFML2A | c.1689G>C p.E563D | Missense Mutation (SNP) | VAF 120/271 reads (44%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- PCDHB6 | c.91C>T p.Q31* | Nonsense Mutation (SNP) | VAF 74/281 reads (26%) | called by muse, mutect2, varscan2
- PRICKLE1 | c.2413C>A p.L805I | Missense Mutation (SNP) | VAF 80/666 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- PRSS33 | c.175G>A p.A59T | Missense Mutation (SNP) | VAF 20/264 reads (8%) | SIFT tolerated (0.62); PolyPhen benign (0.003); called by muse, mutect2
- RAP1GDS1 | c.1103G>A p.R368K (on ENST00000408927 / NM_001100427.2; = p.R369K on NM_021159.5) | Missense Mutation (SNP) | VAF 24/125 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- RELN | c.9716G>A p.G3239E | Missense Mutation (SNP) | VAF 201/752 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- RPA4 | c.250G>C p.E84Q | Missense Mutation (SNP) | VAF 99/111 reads (89%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); called by muse, mutect2, varscan2
- SERTAD3 | c.121G>C p.V41L | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT tolerated (0.64); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- SLC6A16 | c.1329T>G p.N443K | Missense Mutation (SNP) | VAF 99/318 reads (31%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.553); called by muse, mutect2, varscan2
- SOS2 | c.1909G>A p.E637K | Missense Mutation (SNP) | VAF 19/240 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.056); called by muse, mutect2
- SPAG6 | c.1431T>G p.I477M | Missense Mutation (SNP) | VAF 6/122 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- SPDYE1 | c.621C>G p.F207L | Missense Mutation (SNP) | VAF 222/841 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.194); called by muse, mutect2, varscan2
- STAG1 | c.3073T>G p.Y1025D | Missense Mutation (SNP) | VAF 82/268 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, varscan2
- TRMT10B | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 74/195 reads (38%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- WDFY3 | c.8917C>T p.H2973Y | Missense Mutation (SNP) | VAF 72/269 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF665 | c.309G>T p.E103D (on ENST00000600412; = p.E168D on NM_024733.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 50/179 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- ZNF780A | c.24C>G p.F8L | Missense Mutation (SNP) | VAF 161/180 reads (89%) | SIFT deleterious (0); PolyPhen possibly damaging (0.579); called by muse, mutect2, varscan2
- ZNF800 | c.1760C>T p.S587L | Missense Mutation (SNP) | VAF 124/298 reads (42%) | SIFT tolerated (0.38); PolyPhen benign (0.003); called by muse, varscan2
- ATP2A1 | c.987G>A p.K329= | Silent (SNP) | VAF 170/388 reads (44%) | called by muse, mutect2, varscan2
- CATSPERD | c.1713C>A p.G571= | Silent (SNP) | VAF 55/148 reads (37%) | called by muse, mutect2, varscan2
- COL15A1 | c.1608G>A p.L536= | Silent (SNP) | VAF 48/120 reads (40%) | called by muse, mutect2, varscan2
- COL6A3 | c.1872C>G p.L624= | Silent (SNP) | VAF 242/274 reads (88%) | catalogued as COSV55086748; called by muse, mutect2, varscan2
- DDX49 | c.531G>A p.P177= | Silent (SNP) | VAF 121/320 reads (38%) | catalogued as rs747220727, COSV53232382; called by muse, mutect2, varscan2
- DHX37 | c.231G>A p.K77= | Silent (SNP) | VAF 123/307 reads (40%) | called by muse, mutect2, varscan2
- DPH2 | c.366C>T p.F122= | Silent (SNP) | VAF 130/899 reads (14%) | catalogued as rs999912667; called by muse, mutect2, varscan2
- GPR50 | c.168C>T p.N56= | Silent (SNP) | VAF 85/119 reads (71%) | catalogued as rs1246151000; called by muse, mutect2, varscan2
- ISLR2 | c.1374C>T p.R458= | Silent (SNP) | VAF 69/167 reads (41%) | catalogued as rs780483337; called by muse, mutect2, varscan2
- KCNS2 | c.609C>G p.T203= | Silent (SNP) | VAF 158/595 reads (27%) | catalogued as COSV54637866; called by muse, mutect2, varscan2
- LIN7B | c.63C>T p.L21= | Silent (SNP) | VAF 69/159 reads (43%) | catalogued as rs1447580686, COSV99674359; called by muse, varscan2
- LTBP4 | c.591C>A p.L197= (on ENST00000308370 / NM_001042544.1; = p.L160= on NM_003573.2) | Silent (SNP) | VAF 52/140 reads (37%) | called by muse, mutect2, varscan2
- OSBP | c.2169G>T p.L723= | Silent (SNP) | VAF 286/349 reads (82%) | called by muse, mutect2, varscan2
- PGM1 | c.117C>T p.F39= | Silent (SNP) | VAF 439/1243 reads (35%) | called by muse, mutect2, varscan2
- PRG4 | c.1173C>T p.T391= | Silent (SNP) | VAF 102/816 reads (13%) | catalogued as COSV63356627; called by muse, varscan2
- RAP1GDS1 | c.885C>G p.L295= (on ENST00000408927 / NM_001100427.2; = p.L296= on NM_021159.5) | Silent (SNP) | VAF 28/105 reads (27%) | catalogued as rs369611053; called by muse, mutect2, varscan2
- RFC4 | c.591C>T p.F197= | Silent (SNP) | VAF 48/139 reads (35%) | catalogued as rs1476853269; called by muse, mutect2, varscan2
- SALL4 | c.771G>T p.L257= | Silent (SNP) | VAF 93/406 reads (23%) | called by muse, mutect2, varscan2
- SLC24A1 | c.2013C>T p.I671= | Silent (SNP) | VAF 126/324 reads (39%) | called by muse, mutect2, varscan2
- SPOUT1 | c.579C>T p.I193= | Silent (SNP) | VAF 174/185 reads (94%) | catalogued as rs1205045558; called by muse, mutect2, varscan2
- SSTR4 | c.411C>T p.L137= | Silent (SNP) | VAF 38/174 reads (22%) | called by muse, mutect2, varscan2
- THEMIS | c.1083A>G p.E361= | Silent (SNP) | VAF 104/148 reads (70%) | catalogued as rs1021485276; called by muse, mutect2, varscan2
- ZC3HAV1 | c.1566G>T p.P522= | Silent (SNP) | VAF 42/223 reads (19%) | called by muse, mutect2, varscan2
- ZNF648 | c.1134G>C p.S378= | Silent (SNP) | VAF 68/573 reads (12%) | catalogued as COSV60572374; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65503582 A>G | 5'Flank (SNP) | VAF 27/75 reads (36%) | called by muse, mutect2, varscan2
- CD19 | c.1085-25C>T | Intron (SNP) | VAF 55/112 reads (49%) | catalogued as rs770883566; called by muse, mutect2, varscan2
- CTSF | c.-10C>T | 5'UTR (SNP) | VAF 19/253 reads (8%) | called by muse, mutect2
- ENDOV | c.-25C>G | 5'UTR (SNP) | VAF 172/438 reads (39%) | called by muse, mutect2, varscan2
- IFT57 | c.494+31_494+33del | Intron (DEL) | VAF 8/28 reads (29%) | called by mutect2, varscan2
- MCRIP1 | c.-48-1189C>A | Intron (SNP) | VAF 110/259 reads (42%) | called by muse, mutect2, varscan2
- MYO10 | c.-37G>C | 5'UTR (SNP) | VAF 146/311 reads (47%) | called by muse, mutect2, varscan2
- NEFH | c.*34G>T | 3'UTR (SNP) | VAF 206/499 reads (41%) | called by muse, mutect2, varscan2
- NUBP2 | c.16+12G>C | Intron (SNP) | VAF 11/46 reads (24%) | catalogued as rs961256046; called by muse, mutect2
- PRKAG3 | c.775-43G>A | Intron (SNP) | VAF 122/285 reads (43%) | called by muse, mutect2, varscan2
- RPL12 | c.37+10C>T | Intron (SNP) | VAF 46/111 reads (41%) | catalogued as rs1231047163; called by muse, mutect2, varscan2
- SDHAP2 | n.1083G>C | RNA (SNP) | VAF 89/220 reads (40%) | called by muse, mutect2, varscan2
- SMARCA4 | c.2505+17G>A | Intron (SNP) | VAF 167/423 reads (39%) | called by muse, mutect2, varscan2
- TSC2 | c.3884-54G>A | Intron (SNP) | VAF 67/205 reads (33%) | called by muse, mutect2, varscan2
- TTBK2 | c.823-7191G>A | Intron (SNP) | VAF 137/358 reads (38%) | catalogued as rs771535501; called by muse, mutect2, varscan2
- YARS1 | c.1334+48G>C | Intron (SNP) | VAF 166/186 reads (89%) | called by muse, mutect2, varscan2
- ZNF692 | c.-12-196C>T | Intron (SNP) | VAF 98/652 reads (15%) | called by muse, mutect2, varscan2
